Somatic mutation profile of tumor specimen ALCH-AEEW-TTP1-A (aliquot ALCH-AEEW-TTP1-A-1-0-D-A612-36) from ALCHEMIST case ALCH-AEEW, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.1 years (25,245 days).
Specimen ALCH-AEEW-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9f32a00e-f4bc-4a8d-b874-f04046bff474.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEEW-NB1-A (Blood Derived Normal), aliquot ALCH-AEEW-NB1-A-1-0-D-A612-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ba5df893-69b5-4eb5-9536-bfc4b8683dcc

The open-access MAF lists 24 somatic variants for this specimen: 14 protein-altering or splice-affecting, 7 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 7, Intron 3, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 101/933 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- EGFR | c.2947G>A p.G983R | Missense Mutation (SNP) | VAF 90/886 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.375); catalogued as COSV51772666; called by muse, mutect2
- MRGPRE | c.527C>T p.T176M | Missense Mutation (SNP) | VAF 24/192 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as rs781554426, COSV67745687; called by muse, mutect2, varscan2
- SLC6A8 | c.1396G>T p.G466W | Missense Mutation (SNP) | VAF 34/719 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM109753; called by muse, mutect2
- TLE6 | c.180G>A p.S60= | Splice Region (SNP) | VAF 12/305 reads (4%) | catalogued as rs1481492007, COSV55734638; called by muse, mutect2
- ZNF114 | c.680G>A p.G227E | Missense Mutation (SNP) | VAF 26/370 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.667); catalogued as COSV100251879; called by muse, mutect2
- CARD11 | c.1012G>C p.D338H | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); called by muse, mutect2
- ING5 | c.109+1G>A p.X37_splice | Splice Site (SNP) | VAF 17/333 reads (5%) | called by muse, mutect2
- MEIOC | c.1840A>G p.S614G | Missense Mutation (SNP) | VAF 49/485 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PABPC4 | c.1823C>A p.S608Y | Missense Mutation (SNP) | VAF 22/306 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); called by muse, mutect2
- SLC4A7 | c.676A>T p.S226C | Missense Mutation (SNP) | VAF 33/622 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2
- SMTNL1 | c.82G>A p.G28R | Missense Mutation (SNP) | VAF 28/247 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM131L | c.3929G>A p.S1310N | Missense Mutation (SNP) | VAF 22/636 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ZNF184 | c.19C>T p.P7S | Missense Mutation (SNP) | VAF 24/321 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2
- CHST9 | c.906T>C p.H302= | Silent (SNP) | VAF 40/617 reads (6%) | called by muse, mutect2
- CNTNAP5 | c.24C>A p.T8= | Silent (SNP) | VAF 30/625 reads (5%) | called by muse, mutect2
- DPYS | c.303C>T p.F101= | Silent (SNP) | VAF 39/690 reads (6%) | catalogued as rs141057778; called by muse, mutect2
- FMO1 | c.1095C>T p.T365= | Silent (SNP) | VAF 22/370 reads (6%) | called by muse, mutect2
- KAZN | c.36A>T p.T12= | Silent (SNP) | VAF 18/480 reads (4%) | called by muse, mutect2
- MYL4 | c.96G>A p.E32= | Silent (SNP) | VAF 26/462 reads (6%) | called by muse, mutect2
- RNF130 | c.583C>T p.L195= | Silent (SNP) | VAF 24/678 reads (4%) | called by muse, mutect2
- CDK13 | c.2600+14C>G | Intron (SNP) | VAF 13/362 reads (4%) | called by muse, mutect2
- NME1-NME2 | c.546+21C>T | Intron (SNP) | VAF 20/464 reads (4%) | called by muse, mutect2
- SGSH | c.663+34G>A | Intron (SNP) | VAF 26/434 reads (6%) | catalogued as rs781436148; called by muse, mutect2
